Somatic mutation profile of tumor specimen MP2PRT-PAUGNP-TMP1-A (aliquot MP2PRT-PAUGNP-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUGNP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,311 days).
Specimen MP2PRT-PAUGNP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc78a61e-8fb8-4799-8687-77c6c61d8342.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGNP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGNP-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35e39e4b-e92a-4319-b756-1f111f5f51c7

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIGO | c.2402A>G p.Y801C | Missense Mutation (SNP) | VAF 333/1132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774796768; called by muse, mutect2, varscan2
- FANCM | c.4856G>A p.S1619N | Missense Mutation (SNP) | VAF 200/803 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- IGHD2-2 | c.25_31delinsTCCCCT p.L9Sfs*? | Frame Shift Del (DEL) | VAF 92/128 reads (72%) | called by pindel, varscan2*
- NR2F2 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 36/834 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBTB8A | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 182/441 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SALL3 | c.1572G>A p.T524= | Silent (SNP) | VAF 598/1926 reads (31%) | called by muse, mutect2, varscan2
